Surgical pathology report (de-identified scan), TCGA case TCGA-08-0358, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0358-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

TCGA-08-0358

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, right parietal, excision: **Glioblastoma multiforme (Astrocytoma, WHO grade IV).**
- B. Brain, right parietal, excision: **Glioblastoma multiforme (Astrocytoma, WHO grade IV).**

Intraoperative Diagnosis

Brain, right parietal lesion, biopsy: Consistent with astrocytoma grade IV glioblastoma multiforme, however cannot rule out an oligodendroglial component but in either case, this tumor would be a grade IV neoplasm.

Gross Description

The specimen is received in two parts, each labeled with the patient's name and medical record number.

Part A is received fresh and is additionally labeled "right parietal tumor." It consists of a single portion of red-brown, soft tissue, measuring 2.0 x 1.0 x 1.0 cm. A representative section is removed and submitted for intraoperative diagnosis by touch prep and smear. The remainder of the specimen is submitted A1. A small portion (5 x 4 x 3 mm) is frozen for research purposes.

Part B is additionally labeled "right parietal tumor." It consists of an unoriented fragment of tan and pink, soft tissue, measuring 1.5 x 1.0 x 1.3 cm in greatest dimensions. The specimen is bisected and entirely submitted in cassette B1.

Clinical History

The patient is a [REDACTED] with a right parietal tumor and no history of radiation or chemotherapy.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file 708dec08-ffad-4af2-9631-159c59caa6ce (TCGA-08-0358.0A3754ED-0755-45CE-97A7-E4BCBA46948E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).